Gene-level copy-number profile of tumor specimen TCGA-86-7713-01A from TCGA case TCGA-86-7713, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.6 years (25,791 days).
Specimen TCGA-86-7713-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.66b622a8-9efd-4953-a28b-efad389c784f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-7713-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5b9ef20-8035-42e5-997a-226cbd7d713a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13,541; copy number 3: 13,083; copy number 4: 25,220; copy number 5: 5,539; copy number 6: 699; copy number 7: 276; copy number 8: 275; copy number 9: 7; copy number 10: 489; copy number 11: 9; copy number 15: 124; copy number 16: 213; copy number 17: 6; copy number 18: 85; copy number 20: 6; copy number 21: 39; copy number 23: 13; copy number 27: 12; copy number 28: 2; copy number 29: 86; copy number 32: 90; copy number 33: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-7713-01A-11D-2062-01): tumor purity 0.65, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,183 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:49,740,216–51,321,118, 10 genes, copy number 9–17: PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1.
- chr8:51,435,602–51,436,509, 1 gene, copy number 17: BRIX1P1.
- chr8:54,130,582–62,249,879, 124 genes, copy number 15 (broad region; genes not listed).
- chr8:64,973,488–71,592,025, 102 genes, copy number 16 (within-gene range 4–16) (broad region; genes not listed).
- chr8:72,947,150–76,913,399, 70 genes, copy number 16 (broad region; genes not listed).
- chr8:79,259,402–80,930,081, 41 genes, copy number 16 (within-gene range 4–16): AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1.
- chr8:83,403,758–88,887,573, 75 genes, copy number 10 (broad region; genes not listed).
- chr8:115,408,496–145,066,685, 507 genes, copy number 10–29 (broad region; genes not listed).
- chr18:2,847,006–4,459,458, 39 genes, copy number 18 (within-gene range 8–18): EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27.
- chr18:25,818,234–45,181,382, 214 genes, copy number 17–33 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
